Gene-level copy-number profile of tumor specimen ALCH-B1NF-TTP1-A from ALCHEMIST case ALCH-B1NF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.9 years (27,731 days).
Specimen ALCH-B1NF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9ea66764-3b1e-458e-b11a-4aef41c6cd4b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1NF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/0fabf648-2ac0-4db7-a0d0-992314e829c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 295; copy number 2: 52,168; copy number 3: 5,883; copy number 4: 14; copy number 5: 40.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:48,986,275–49,062,081, 2 genes, copy number 5: CWH43, TPI1P4.
- chr22:16,653,892–17,266,733, 38 genes, copy number 5 (within-gene range 2–5): PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1, ADA2, AC005300.1, FAM32BP, CECR3.

Autosomal genes at a single copy (total copy number 1): 249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
